Gene-level copy-number profile of tumor specimen ALCH-ABZH-TTP1-A from ALCHEMIST case ALCH-ABZH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,599 days).
Specimen ALCH-ABZH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d7d2510-f639-4e6f-a274-7617e67c34d2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABZH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/7d35dc04-e72e-4e80-bb4a-5d3ec99bfef1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 871; copy number 2: 55,593; copy number 3: 1,914; copy number 4: 9; copy number 5: 3; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:25,243,614–25,250,940, 5 genes (within-gene range 0–2): SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:170,639,606–170,640,536, 1 gene, copy number 5: OR4F7P.
- chr22:18,178,038–18,345,899, 2 genes, copy number 5: FAM230D, GGTLC5P.
- chr22:18,527,802–18,530,573, 1 gene, copy number 6: TMEM191B.

Autosomal genes at a single copy (total copy number 1): 836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
